Somatic mutation profile of tumor specimen TCGA-24-2036-01A (aliquot TCGA-24-2036-01A-01W-0722-08) from TCGA case TCGA-24-2036, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 50.9 years (18,582 days).
Specimen TCGA-24-2036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e3c7611-b7e6-46b0-b448-fb3b5561bdf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2036-10A (Blood Derived Normal), aliquot TCGA-24-2036-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7969c3a-dfb9-406e-8fd2-b6bd6ed206c6

The open-access MAF lists 57 somatic variants for this specimen: 49 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 6, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 17/19 reads (89%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.027); catalogued as COSV100750990; called by muse, mutect2, varscan2
- AGGF1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV100462106; called by muse, mutect2, varscan2
- ARMC5 | c.2183T>A p.L728Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV99192693, COSV99192864; called by muse, mutect2, varscan2
- ATP9B | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as COSV100303943; called by muse, mutect2, varscan2
- CMYA5 | c.8291T>C p.F2764S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV101484228; called by muse, mutect2, varscan2
- CSDE1 | c.946G>T p.V316F (on ENST00000358528 / NM_001007553.3; = p.V285F on NM_007158.6) | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99795571; called by muse, mutect2, varscan2
- DNASE1L1 | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99186164; called by muse, mutect2, varscan2
- DOCK2 | c.2867T>C p.I956T | Missense Mutation (SNP) | VAF 269/525 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs188136128; called by muse, mutect2, varscan2
- EVA1C | c.867C>A p.N289K | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100291506; called by muse, mutect2, varscan2
- FCMR | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 138/508 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as rs762880718, COSV65569929; called by muse, mutect2, varscan2
- FLNB | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as COSV99914087; called by muse, mutect2, varscan2
- FOLH1 | c.1454A>G p.D485G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV99923591; called by muse, mutect2
- GABBR2 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1237050820, COSV99410900; called by muse, mutect2, varscan2
- IQGAP2 | c.4642G>A p.V1548I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV99167777; called by muse, mutect2, varscan2
- ITIH6 | c.1403A>T p.E468V | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs1298599804, COSV99513690; called by muse, mutect2, varscan2
- KIF17 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs758439125, COSV99929472; called by muse, varscan2
- KMT2A | c.4697-1G>T p.X1566_splice | Splice Site (SNP) | VAF 183/199 reads (92%) | catalogued as COSV100629383; called by muse, mutect2, varscan2
- LRRC17 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 53/113 reads (47%) | catalogued as COSV99978550; called by muse, mutect2, varscan2
- MBD1 | c.1477G>A p.V493M (on ENST00000269468 / NM_001323950.1; = p.V437M on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/174 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs774182305, COSV99496831; called by muse, mutect2, varscan2
- MVD | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs772577920, COSV99964924; called by muse, varscan2
- OR2T35 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100442352; called by muse, mutect2, varscan2
- PADI1 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969203; called by muse, mutect2
- PCDHA3 | c.1251C>A p.S417R | Missense Mutation (SNP) | VAF 129/306 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.118); catalogued as rs782040160, COSV100793616, COSV63545288; called by muse, mutect2, varscan2
- POPDC2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951091; called by muse, mutect2, varscan2
- PROX1 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 166/732 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1000387494, COSV99799906; called by muse, mutect2, varscan2
- PTCHD4 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as COSV100261326; called by muse, mutect2, varscan2
- RANBP2 | c.3821A>C p.E1274A | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99312779; called by muse, mutect2, varscan2
- RFC1 | c.2249G>C p.C750S (on ENST00000381897 / NM_001363496.2; = p.C749S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100567903; called by muse, mutect2, varscan2
- SCN7A | c.3185T>C p.F1062S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV101313315; called by muse, mutect2, varscan2
- SLC11A1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs532410275, COSV51918237, COSV99262318; called by muse, mutect2, varscan2
- SLC45A1 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.489); catalogued as rs756166685, COSV99239312; called by muse, mutect2, varscan2
- SP4 | c.2034A>G p.I678M | Missense Mutation (SNP) | VAF 194/386 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs775843294, COSV99754820; called by muse, mutect2, varscan2
- STAT2 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 127/153 reads (83%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.542); catalogued as COSV100029051; called by muse, mutect2, varscan2
- TALDO1 | c.222-1G>A p.X74_splice | Splice Site (SNP) | VAF 34/73 reads (47%) | catalogued as COSV100032804; called by muse, mutect2, varscan2
- TEX11 | c.554C>G p.S185C (on ENST00000344304; = p.S170C on NM_031276.3) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100722037; called by muse, mutect2, varscan2
- TMEM131 | c.3707G>T p.R1236I | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.347); catalogued as COSV99488889; called by muse, mutect2, varscan2
- TMEM63B | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV52476934; called by muse, mutect2
- TTC6 | c.88C>G p.Q30E (on ENST00000267368; = p.Q1299E on NM_001310135.3) | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99942108; called by muse, mutect2, varscan2
- TTN | c.52090G>A p.A17364T (on ENST00000591111; = p.A9940T on NM_003319.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | PolyPhen benign (0.049); catalogued as COSV100593365, COSV100622550; called by muse, mutect2, varscan2
- TUT7 | c.4038T>G p.C1346W | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99463389; called by muse, mutect2, varscan2
- WASHC4 | c.2460T>G p.I820M | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100162615; called by muse, mutect2, varscan2
- ZNF91 | c.2544T>A p.H848Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100323237; called by muse, mutect2, varscan2
- QPCT | c.56_72del p.V19Gfs*40 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by mutect2, varscan2
- SRCIN1 | c.2799G>T p.K933N (on ENST00000621492; = p.K899N on NM_025248.3) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRAJ26 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 98/179 reads (55%) | called by muse, mutect2, varscan2
- VN1R5 | c.458T>C p.L153S | Missense Mutation (SNP) | VAF 342/680 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- XRCC1 | c.1148_1189del p.K383_P397delinsT | In Frame Del (DEL) | VAF 40/125 reads (32%) | called by mutect2, pindel
- ZNF264 | c.409_422del p.E137Tfs*16 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- AGTR1 | c.750C>T p.F250= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV62557130, COSV62557404; called by muse, mutect2, varscan2
- ARMC5 | c.2182C>T p.L728= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs753445738, COSV51660076, COSV99192691; called by muse, mutect2, varscan2
- FILIP1 | c.2991C>T p.G997= | Silent (SNP) | VAF 112/234 reads (48%) | catalogued as rs776433993, COSV52725047; called by muse, mutect2, varscan2
- LRRC49 | c.1659T>G p.S553= | Silent (SNP) | VAF 131/164 reads (80%) | catalogued as COSV99537875; called by muse, mutect2, varscan2
- RIMS1 | c.3420A>G p.L1140= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV99328916; called by muse, varscan2
- RNF34 | c.921A>G p.Q307= | Silent (SNP) | VAF 81/90 reads (90%) | catalogued as COSV100772140; called by muse, mutect2, varscan2
- KRTAP24-1 | c.*1C>A | 3'UTR (SNP) | VAF 55/121 reads (45%) | catalogued as COSV100447496; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23794C>G | Intron (SNP) | VAF 35/80 reads (44%) | catalogued as COSV101044473; called by muse, mutect2, varscan2
